Surgical pathology report (de-identified scan), TCGA case TCGA-AG-A008, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-A008-01A (Primary Tumor).

Sample ID

Diagnosis:

Rectal resection with a moderately differentiated mucinous adenocarcinoma with infiltration of the muscularis propria. A further tubular adenoma with profound dysplasia (synonymous: profound intraepithelial neoplasia) and passage to an intramucosal carcinoma. Diverticulosis. Tumor-free resection margins. Tumor-free lymph nodes (28 lymph nodes examined).

Tumor classification: G2, pT2 N0 L0 V0 R0.

ICD-0-3

Adenocarcinoma, mucinous, NOS 8480/3

site: Rectum C20.9 /w 2/31/11

Source: NCI Genomic Data Commons file 01bcbdb2-df08-4121-a816-36f4346b8f0a (TCGA-AG-A008.DF4361B8-1FE8-4CDA-8AA6-B76EDF7D478F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).